BEATAML1.0 case 2451 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/fcdc7feb-5fce-4089-8086-33b262eca7e2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with mutated NPM1: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,935 days); Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (1 sample)
- Sample BA2335D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
